CCDI case PBCSFL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9d2970bf-8be9-4578-a056-a29edb7c7f21

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 4.0 years (1,474 days).

Biospecimens (3 samples)
- Sample 0DY43C: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DY43X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DY44K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
